Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7125, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7125-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN NINE (9) LYMPH NODES EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN FOUR (4) LYMPH NODES EXAMINED.

TCGA-EJ-7125

PART 3:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7.
- B. TUMOR INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.1 CM.
- C. THE TUMOR INVOLVES APPROXIMATELY 20% OF THE TOTAL PROSTATE VOLUME.
- D. THE TUMOR IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF TUMOR.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF TUMOR.
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. OCCASIONAL FOCI OF HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA ARE IDENTIFIED.
- J. TNM PATHOLOGIC STAGE = pT2c N0 MX.

MICROSCOPIC:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	15%
WEIGHT OF PROSTATE:	55.7gm
TUMOR SIZE:	Maximum dimension: 2.1 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	13
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 7dbedb94-e4fa-49d3-85a4-599c9d7ac6bc (TCGA-EJ-7125.3565CC83-8305-490F-A47A-DC71B36A9044.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).